Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A75L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A75L-01A (Primary Tumor).

Final Diagnosis:

A-B. Brain, left frontal lobe, biopsy and CUSA contents, excision: Anaplastic astrocytoma (WHO grade III).

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to p53 protein and mutant IDH1 (IDH1 R132H).

p53 protein: Strongly overexpressed in tumor cells.

Mutant IDH1 (IDH1 R132H): Positive, consistent with IDH1 mutation.

Participated in interpretation:

Interpreted by:

Report electronically signed by:

Transcribed by:

ICD-O-3
Astrocytoma, grade III
9461/3
Site (L) Brain, supratentorial NOS
C71.0
JW 8/12/13

Preliminary Frozen Section Consultation:

A. Brain, left frontal, excision: Intermediate grade glioma.

to characterize.

Intraoperative cytologic (smears) interpretation performed by:

ALL EMBEDDED

continued next page Page 1 of 2

Source: NCI Genomic Data Commons file d88b0665-0572-482e-8de6-056e04845626 (TCGA-DB-A75L.A725AA31-18ED-47A2-9393-E811952AD9B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).